Gene-level copy-number profile of tumor specimen TCGA-VQ-A94R-01A from TCGA case TCGA-VQ-A94R, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 63.6 years (23,246 days).
Specimen TCGA-VQ-A94R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d189dbe2-ec74-41b0-9aea-77d9c1ec2129.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A94R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7036c1c-2b5c-498d-871a-a68dbbe70b31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 20,625; copy number 2: 28,172; copy number 3: 6,439; copy number 4: 3,948; copy number 5: 511; copy number 6: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A94R-01A-11D-A40Z-01): tumor purity 0.69, ploidy 2.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,915,871–8,344,167, 16 genes: TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr2:231,362,708–231,362,793, 1 gene: MIR4777.
- chr2:241,149,576–241,804,287, 24 genes (within-gene range 0–2): PPP1R7, ANO7, HDLBP, SEPTIN2, AC104841.1, AC005104.1, FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1, THAP4, RNA5SP122, ATG4B, DTYMK, ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2.
- chr6:14,152,196–14,211,186, 1 gene (within-gene range 0–1): AL133259.1.
- chr6:14,210,293–15,090,170, 9 genes (within-gene range 0–2): AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1.
- chr18:50,968,019–51,058,144, 1 gene (within-gene range 0–1): AC091551.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 576 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,997,168–68,545,621, 11 genes, copy number 5 (within-gene range 4–5): AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1.
- chr6:41,026,895–47,722,021, 188 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:130,004,528–132,760,712, 25 genes, copy number 5: RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1.
- chr20:10,672,695–10,994,924, 1 gene, copy number 5 (within-gene range 4–5): AL050403.2.
- chr20:10,753,278–16,053,197, 51 genes, copy number 5 (within-gene range 4–5): AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr20:15,892,355–31,607,240, 300 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
